Gene-level copy-number profile of tumor specimen MP2PRT-PAXVZT-TTM2-A from MP2PRT case MP2PRT-PAXVZT, project MP2PRT-WT (Molecular Profiling to Predict Response to Treatment - Wilms Tumor). Sex at birth: male; Vital status: Alive; Primary diagnosis: Nephroblastoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 3.7 years (1,363 days).
Specimen MP2PRT-PAXVZT-TTM2-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 605d8bf4-9916-432a-8002-11a2bc982b88.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAXVZT-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,726 have no estimate.
https://portal.gdc.cancer.gov/files/01316cac-f0ef-48e0-9b3f-fa629da301ae

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 15; copy number 1: 6,961; copy number 2: 49,062; copy number 3: 2,841; copy number 4: 13; copy number 6: 5.

Homozygous deletions (total copy number 0; autosomes only): 15 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:6,785,454–7,769,706, 10 genes (within-gene range 0–1): CAMTA1, AL590128.1, AL512330.1, RNU1-8P, CAMTA1-IT1, CAMTA1-AS2, CAMTA1-AS1, AL359881.3, AL359881.2, AL359881.1.
- chr1:33,261,212–33,261,680, 1 gene (within-gene range 0–1): AL513327.2.
- chr22:30,425,623–30,472,017, 4 genes (within-gene range 0–1): MTFP1, AC004832.6, AC004832.2, SEC14L3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:121,108,210–121,185,539, 5 genes, copy number 6 (within-gene range 3–6): H2BP1, AC244453.1, H3P4, RPL22P6, FAM72B.

Autosomal genes at a single copy (total copy number 1): 4,105. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
